Surgical pathology report (de-identified scan), TCGA case TCGA-A4-A7UZ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-A7UZ-01A (Primary Tumor).

[page 1 of 5]
Patient Results

M

Surgical Pathology

Path Report

Final

Final

SURGICAL PATHOLOGY REPORT

ACCESSION NO. :

Final Diagnosis(es):

(A) Left kidney and adrenal gland, radical nephrectomy:

1) Papillary renal cell carcinoma (5.5 cm), Type 2, Fuhrman grade 3 of 4 (see Synoptic Report).

2) Tumor focally invades renal sinus.

3) Separate tumor focus located in proximal ureter (0.7 cm).

4) Pathologic stage: pT3a N1 MX.

5) Adrenal gland with no pathologic abnormality.

(B) Left adrenal gland, completion adrenalectomy:

1) Benign adrenal gland.

2) No malignancy identified.

(C) Lymph nodes, para-aortic, excision:

1) Metastatic papillary renal cell carcinoma involving two of two lymph nodes (2/2).

2) Extracapsular extension identified.

(D) Lymph nodes, para-aortic, excision:

1) Metastatic papillary renal cell carcinoma involving ten of sixteen lymph nodes (10/16).

2) Extracapsular extension identified.

3) Vascular invasion present.

(E) Lymph nodes, interaortocaval, excision:

1) Metastatic papillary renal cell carcinoma involving two of two lymph nodes (2/2).

2) Vascular invasion present.

(F) Ureter, left distal, ureterectomy: Benign ureter, negative for malignancy.

Synoptic Report:

Laterality: Left.

Specimen Procedure: Radical nephrectomy.

Tumor Site: Middle.

Tumor Size: 5.5 x 5.0 x 4.5 cm.

Tumor Focality: Multifocal (kidney and ureter)

Macroscopic Extent of Tumor: Limited to kidney.

Histologic Type: Papillary renal cell carcinoma.

Sarcomatoid Features: Not identified.

Tumor Necrosis: Present, 5%.

Histologic Grade (Fuhrman Nuclear Grade): Grade 3, Type 2.

Microscopic Extent of Tumor: Renal sinus, focal.

Lymphovascular Invasion: Present.

Margins:

Ureteric: Negative.

Vascular: Negative.

Soft Tissue: Negative.

Regional lymph nodes:

ICD O-3

Carcinoma, papillary renal cell

8260/3

Site @ Kidney NOS

C64.9

10/4/13

Printed from:

[page 2 of 5]
Patient Results

M

Number examined: 20

Number positive: 14

Pathologic Staging: pT3a N1 MX.

Pathologic Findings in Non-Neoplastic Kidney: Mild, patchy, interstitial, chronic inflammation.

Immunohistochemistry:

RCC: Positive

PAX-8: Positive

CD10: Positive

CK5: Negative

p63: Negative

Comments:

The morphologic features and immunohistochemical profile supports the diagnosis of papillary renal cell carcinoma.

Although spread into the ureter is unusual for renal cell carcinoma, the main kidney mass and tumor within the ureter share the same immunohistochemical profile and morphologic appearance, representing the same tumor.

This case has been reviewed and the diagnosis agreed upon by consulting departmental surgical pathology staff.

The gross description and all microscopic slides have been reviewed and interpreted by the undersigned pathologist

Electronically Signed

Specimen(s) Received:

A: Left kidney and adrenal gland

B: Left adrenal gland

C: Para-aortic lymph nodes

D: Para-aortic lymph nodes

E: Part of intraaorta caval

F: Distal ureter, left

Clinical History:

Left kidney cancer.

Intraoperative Consultation:

Time Received:

Time Reported:

FSA1-FSA2: Left kidney mass: Carcinoma, favor urothelial (2 blocks).

FSC1-FSC2: Paraaortic lymph node: Metastatic carcinoma, favor papillary renal cell carcinoma (2 blocks).

Gross Description:

(A) (left kidney and adrenal gland)

Specimen components and dimensions: Received fresh for frozen section analysis is a kidney and perinephric fat measuring 29.0

Printed from:

Page: 2 of 6

[page 3 of 5]
Patient Results

M

x 23.0 x 6.0 cm. The specimen weighs 1,270 gm. The kidney itself measures 12.0 x 6.5 x 5.0 cm. The attached adrenal gland measures 4.5 x 1.5 x 1.0 cm. The attached ureter measures 5.5 cm in length and has an average diameter of 0.4 cm. The kidney has been shelled out of the perinephric fat and bivalved by the surgeon. The perinephric fat is inked black. The capsular surface of the kidney is tan-brown. There are multiple small white granular lesions ranging in size from 0.1 to 0.5 cm on the surface. A portion of the tumor appears to be pushing the capsule out and this area measures 4.5 x 3.0 x 2.6 cm. It does not appear to be grossly invading through the capsule. Size, appearance and location of tumor: Bivalving the specimen reveals a tan-white to pink friable mass (5.5 x 5.0 x 4.5 cm) present within the center of the kidney. There is an additional small tan-pink nodule (0.7 x 0.5 x 0.4 cm) at the proximal ureter. A representative section of the smaller mass is submitted in FSA1. A representative section of the large tumor is submitted in FSA2.

Renal capsule/Renal sinus: The tumor appears to be extending the capsule, but does not appear to grossly invade through the capsule into the perinephric fat. The tumor appears to abut the renal sinus; however, no gross invasion is identified. The small mass on the ureter does not appear to grossly invade into the ureter.

Renal vein: Not clearly identified.

Other findings: None.

Uninvolved tissues: The adrenal gland appears golden yellow with small punctate hemorrhage areas present. The uninvolved renal parenchyma appears tan-brown. The medulla is tan-pink. The average cortical thickness is 0.9 cm. The uninvolved ureter serosa is tan-pink, smooth and glistening. The uninvolved ureter mucosa is tan-white and striated.

Lymph nodes: Five potential lymph nodes are identified in the hilum fat ranging in size from 0.4 to 1.1 cm. The larger nodes are firm and suspicious for tumor involvement.

Blocks submitted:

FSA1-FSA2 - representative tumor (large mass and smaller ureteral mass, respectively)

A3 - representative shave margin of all vascular structures identified.

A4 - entire small lesion found on the ureter and cross sections

A5-A6 - representative sections of the tumor and its relationship to the sinus fat

A7 - representative section of the tumor and its relationship to the renal pelvis and sinus fat

A8 - representative section of the tumor and its relationship to the uninvolved renal parenchyma

A9-A10 - representative section of the tumor and in its relationship to the capsule where it protrudes

A11 - representative section of perinephric fat

Printed from:

Page: 3 of 6

[page 4 of 5]
Patient Results

M

A12 - representative section of grossly uninvolved renal parenchyma and uninvolved ureter

A13 - five potential lymph nodes intact

A14 - adrenal gland

(B) (left adrenal gland) Received in formalin is a portion of adrenal gland measuring 5.5 x 3.5 x 3.5 cm. The adrenal gland is golden yellow with red hemorrhagic tissue within the center. Serial sectioning of the adrenal gland demonstrates no grossly identified masses. Representative sections are submitted in cassettes B1-B3.

(C) (para-aortic lymph nodes) Received fresh for frozen section is tan-red tissue measuring 5.0 x 2.5 x 2.0 cm. Three firm lymph nodes are identified ranging in size from 1.2 to 4.0 cm. the smallest lymph node is inked black and submitted intact along with one representative section of the middle-sized lymph node in FSC1. A representative section of the largest lymph node is submitted in FSC2. The remainder of the middle-sized lymph node is serially sectioned and submitted entirely in cassette C3. The largest lymph node is serially sectioned and submitted in cassettes C4-C6.

(D) (para-aortic lymph nodes) Received in formalin are two fragments of tan-red fibroadipose tissue measuring 7.0 x 10.5 x 4.0 cm. There are multiple surgical clips and sutures present. Additionally present are fragments of a vascular structure. Sixteen potential lymph nodes are identified which are firm and rang in size from 0.4 to 6.0 cm. Blocks are submitted as follows:

D1 - representative sections of the vascular structures identified within the specimen

D2 - six potential lymph nodes intact

D3 - three potential lymph nodes intact

D4 - one matted lymph node bisected

D5 - one potential lymph node bisected

D6-D8 - one lymph node serially sectioned

D9-D10 - one lymph node serially sectioned

D11-D14 - one lymph node serially sectioned

D15-D16 - representative sections of one lymph node

D17-D19 - representative sections of the largest lymph node

(E) (part of interaortocaval) Received in formalin is one fragment of tan-pink fibroadipose tissue measuring 5.5 x 5.5 x 3.0 cm. Two large firm matted lymph nodes are identified ranging in size from 3.0 x 5.5 cm. Blocks are submitted as follows:

E1-E2 - representative sections from the smaller matted lymph node

E3-E5 - representative sections of the larger matted lymph node

(F) (distal ureter, left) Received in formalin is a portion of ureter measuring 5.0 cm in length and having a diameter ranging from 0.6 to 0.5 cm. There is a stapled and suture on one end of the ureter. This end of the ureter is inked blue. The ureter

Printed from:

Page: 4 of 6

[page 5 of 5]
Patient Results

M

is serially sectioned. Blocks are submitted as follows:
F1 - the inked blue margin which was the one with a staple and suture on it as well as the opposite margin
F2 - the remainder of the specimen serially sectioned

Microscopic Description:

Complete microscopic evaluation has been performed.

Appropriately reacting controls have been performed and evaluated for all stains on this case as required. Histopathology has a list of IH antibodies that are regulated as analyte specific reagents (ASR's). These assays were developed and their performance characteristics determined by the

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary for the ASR's. These tests are not investigational and are used in standard clinical care. In cases where Immunohistochemistry testing is performed, the following antibodies and their respective clones may be used to determine therapy for the patient: EFGR(3c6), ER(SP1), PR(1E2), Her2neu(4B5), CD117(Poly), CD20(L26) Ki67(30-9). Unless otherwise stated in the report, all tissue tested for ERPR by IHC, Her2 by IHC and/or HER2 by FISH have been fixed as per C.A.P. requirements for a minimum of 6 hours and a maximum of 48 hours.

ER, PR, Ki-67, p53 are reported as a semi-quantitative percentage of positively stained nuclei. Her-2/neu and EGFR are scored as follows: No staining at all is scored as (0), weak, incomplete membrane staining in any proportion of cells is scored as (1+), less than strong but complete staining in any proportion of cells or complete strong staining in less than 30% of cells is scored as (2+), and strong complete staining in more than 30% of cells is scored as (3+). All studies are performed on tissue fixed in 10% neutral buffered formalin and embedded in paraffin unless otherwise stated in the report.

Reviewed	9/28/13	9/28/13

Printed from:

Source: NCI Genomic Data Commons file 6c849c0f-3207-4e24-8d14-ed2272be7427 (TCGA-A4-A7UZ.B67F4143-2D87-4682-B17B-23C6D99D02B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).